Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAIH, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAIH-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; seminoma; diameter 4.0 cm; no angio-invasion; no invasion in rete testis;
invasion of tunica albuginea present; lymphatic invasion present; epididymis free of tumor;
surgical margin of spermatic cord free of tumor.

Date of procurement (= date of orchidectomy):

ICD O-3

Seminoma NOS 9061/3
Site: @ Testis NOS C62.9
JW 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file e88da54c-f69b-481c-aa84-428c390b9dfc (TCGA-2G-AAIH-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).